Somatic mutation profile of tumor specimen TARGET-20-PASMYP-03A (aliquot TARGET-20-PASMYP-03A-01D) from TARGET case TARGET-20-PASMYP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.4 years (5,618 days).
Specimen TARGET-20-PASMYP-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 017ff639-4496-404e-af68-1e6fc18357dc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASMYP-14A (Bone Marrow Normal), aliquot TARGET-20-PASMYP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f5dddcc-3406-4304-a0fa-5fc03e21e13c

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs121918466, CM013420, CM032349, COSV61005872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV54046796; called by muse, mutect2
- MACF1 | c.13027T>C p.L4343= (on ENST00000372915; = p.L2276= on NM_012090.5) | Silent (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- PRUNE1 | c.*1343C>A | 3'UTR (SNP) | VAF 80/170 reads (47%) | called by muse, mutect2, varscan2
